Gene-level copy-number profile of tumor specimen TCGA-HT-8108-01A from TCGA case TCGA-HT-8108, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 26.1 years (9,539 days).
Specimen TCGA-HT-8108-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.ffbea3a5-3d1c-41d5-aab6-0f75ca09184d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HT-8108-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9a52a737-e169-4eba-aa5c-42a645893fe8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,304; copy number 2: 55,118; copy number 3: 546; copy number 4: 1,480; copy number 5: 371.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HT-8108-01A-11D-2391-01): tumor purity 0.84, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 371 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,019,656–147,788,953, 27 genes, copy number 5: AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2.
- chr1:154,272,589–157,045,742, 156 genes, copy number 5 (broad region; genes not listed).
- chr1:159,927,039–160,372,846, 25 genes, copy number 5: IGSF9, SLAMF9, LINC01133, AL513485.1, KCNJ10, AL513302.1, PIGM, AL121987.1, KCNJ9, IGSF8, ATP1A2, ATP1A4, CASQ1, AL121987.2, PEA15, DCAF8, AL139011.2, AL139011.1, RPSAP18, PEX19, COPA, SUMO1P3, Y_RNA, NCSTN, NHLH1.
- chr1:174,756,850–176,207,286, 25 genes, copy number 5 (within-gene range 2–5): BANF1P4, NDUFAF4P4, Z99127.2, RABGAP1L-IT1, Z99127.1, RABGAP1L-AS1, RNU6-307P, Z99127.3, CACYBP, MRPS14, Y_RNA, ENTR1P2, TNN, KIAA0040, AL008626.1, RPS29P4, Z94057.1, TNR, TNR-IT1, LINC01657, LINC02803, RPS29P5, COP1, SCARNA3, AL590723.1.
- chr1:185,118,101–186,581,191, 32 genes, copy number 5 (within-gene range 2–5): TRMT1L, SWT1, RPL22P24, RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2, LINC01350, Y_RNA, Y_RNA, AL133383.1, HMCN1, AL133553.1, AL133553.2, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2.
- chr1:225,700,264–225,846,522, 7 genes, copy number 5: AC099066.2, AC099066.1, RNU6-1304P, SRP9, AC099066.3, EPHX1, AL591895.1.
- chr7:86,216,785–93,574,730, 99 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,304. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
